Somatic mutation profile of tumor specimen TCGA-18-4721-01A (aliquot TCGA-18-4721-01A-01D-1441-08) from TCGA case TCGA-18-4721, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 74.1 years (27,076 days).
Specimen TCGA-18-4721-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3420b914-f723-4a3f-969e-ccd81b15573f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-4721-11A (Solid Tissue Normal), aliquot TCGA-18-4721-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b3d2db3-8ae3-4d39-bd9b-9d1e7a133b65

The open-access MAF lists 182 somatic variants for this specimen: 129 protein-altering or splice-affecting, 49 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 49, Nonsense Mutation 14, Splice Site 2, Intron 2, Frame Shift Del 2, Frame Shift Ins 1, RNA 1, Splice Region 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 42/102 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- ANO5 | c.1299G>T p.M433I | Missense Mutation (SNP) | VAF 66/288 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV61083589; called by muse, mutect2, varscan2
- ARL1 | c.248C>G p.S83* | Nonsense Mutation (SNP) | VAF 26/136 reads (19%) | catalogued as COSV55370067; called by muse, mutect2, varscan2
- ATG7 | c.2068C>T p.Q690* | Nonsense Mutation (SNP) | VAF 11/87 reads (13%) | catalogued as COSV61611756; called by muse, mutect2, varscan2
- BAX | c.279C>G p.F93L | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV53169676; called by muse, varscan2
- CALN1 | c.323C>A p.S108* (on ENST00000329008 / NM_001017440.3; = p.S150* on NM_031468.4) | Nonsense Mutation (SNP) | VAF 46/157 reads (29%) | catalogued as COSV61125823, COSV61132967; called by muse, mutect2, varscan2
- CD58 | c.509C>G p.S170* | Nonsense Mutation (SNP) | VAF 19/92 reads (21%) | catalogued as COSV59841516; called by muse, mutect2, varscan2
- CDCA5 | c.575C>G p.P192R | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV51868991; called by muse, mutect2, varscan2
- CEP68 | c.942G>T p.Q314H | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.562); catalogued as COSV53124123; called by muse, mutect2, varscan2
- CHD8 | c.7054C>T p.R2352* (on ENST00000646647 / NM_001170629.2; = p.R2073* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as rs756631600, COSV63036622; called by muse, mutect2, varscan2
- CHFR | c.850G>A p.V284I (on ENST00000432561 / NM_001161345.1; = p.V243I on NM_018223.2) | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs199761208, COSV57173113; called by muse, mutect2, varscan2
- CIT | c.3059C>G p.T1020S | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV55864649; called by muse, mutect2, varscan2
- CLCA1 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as COSV52326480, COSV52326871; called by muse, mutect2, varscan2
- CMA1 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51625161; called by muse, mutect2, varscan2
- CMTR2 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57603030; called by muse, mutect2, varscan2
- CNTN3 | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55166957, COSV55173375; called by muse, mutect2, varscan2
- CNTN3 | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV55165808, COSV55166968; called by muse, mutect2, varscan2
- COG2 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 113/275 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1442580926, COSV64186336; called by muse, varscan2
- CPSF4 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as COSV52857019; called by muse, mutect2, varscan2
- CRTAM | c.83T>A p.V28E | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57067172, COSV57067761; called by muse, mutect2, varscan2
- CSMD1 | c.6721T>G p.F2241V (on ENST00000520002; = p.F2240V on NM_033225.6) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV59302625; called by muse, mutect2, varscan2
- CUL3 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 31/147 reads (21%) | catalogued as COSV52363038; called by muse, mutect2, varscan2
- DCUN1D1 | c.389+1G>C p.X130_splice | Splice Site (SNP) | VAF 14/417 reads (3%) | catalogued as COSV53044060, COSV99490117; called by muse, mutect2
- DEFB1 | c.128A>G p.Q43R | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.114); catalogued as COSV52412850; called by muse, mutect2, varscan2
- DLGAP1 | c.2476G>T p.D826Y | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV59794951; called by muse, mutect2
- DNAH12 | c.920C>T p.T307I | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV60856268; called by muse, mutect2, varscan2
- DROSHA | c.3823G>T p.E1275* | Nonsense Mutation (SNP) | VAF 17/102 reads (17%) | catalogued as COSV60774233; called by muse, mutect2, varscan2
- DSC2 | c.2659T>A p.L887M | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51862626; called by muse, mutect2, varscan2
- DSC3 | c.1643C>G p.T548R | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64572367; called by muse, mutect2
- ELP1 | c.2834A>G p.K945R | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.898); catalogued as COSV65897044; called by muse, mutect2, varscan2
- ENTPD6 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV61751238; called by muse, mutect2, varscan2
- EPB41L3 | c.2150A>T p.K717M | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as COSV59448541; called by muse, mutect2
- EPB41L3 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59448555; called by muse, mutect2
- EPB41L3 | c.939A>T p.L313F | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59448568; called by muse, mutect2
- EYS | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.364); catalogued as COSV60981090, COSV60981986; called by muse, mutect2
- FAT3 | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); catalogued as COSV53093141; called by muse, mutect2, varscan2
- FAT3 | c.6925G>T p.V2309F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV53093167; called by muse, mutect2, varscan2
- FLG | c.2357G>T p.R786M | Missense Mutation (SNP) | VAF 48/568 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV64239412; called by muse, mutect2
- FMN2 | c.1846G>T p.G616W | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60425076; called by muse, mutect2, varscan2
- FMN2 | c.2926C>A p.P976T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV60425081; called by muse, mutect2, varscan2
- GABBR2 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1288133373, COSV52299018; called by muse, mutect2, varscan2
- GABRG3 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.714); catalogued as COSV100403912, COSV61513827; called by muse, mutect2, varscan2
- GALNT6 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375356380, COSV62541869; called by muse, mutect2, varscan2
- GALNTL6 | c.500C>A p.T167N | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV71827162; called by muse, mutect2, varscan2
- GPR63 | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV57740543; called by muse, mutect2, varscan2
- H2BC11 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV60361908; called by muse, mutect2, varscan2
- HGF | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.215); catalogued as rs750282888, COSV55947263; called by muse, mutect2, varscan2
- HIVEP1 | c.2173G>A p.G725R | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as rs1203970076, COSV65100093; called by muse, mutect2, varscan2
- JCAD | c.523A>G p.M175V | Missense Mutation (SNP) | VAF 74/289 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.041); catalogued as COSV64758784; called by muse, mutect2, varscan2
- KIAA1210 | c.4984G>T p.V1662F | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV68176399; called by muse, mutect2, varscan2
- KRT2 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59009718; called by muse, mutect2, varscan2
- LAMA2 | c.1081A>G p.R361G | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV69000655; called by muse, mutect2, varscan2
- LAMA3 | c.4850G>A p.R1617H | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.013); catalogued as rs557657738, COSV52532479; called by muse, mutect2, varscan2
- LCA5 | c.602T>G p.F201C | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV63970909; called by muse, mutect2, varscan2
- LCP1 | c.407A>G p.N136S | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV59940223; called by muse, mutect2, varscan2
- LGALS12 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as rs80310877, COSV55369807; called by muse, mutect2, varscan2
- LMX1A | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV54218800; called by muse, mutect2, varscan2
- LRFN1 | c.1627G>A p.V543I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as COSV50437261; called by muse, mutect2, varscan2
- LRIT1 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV64512197; called by muse, mutect2
- LYZL4 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769136882, COSV55103776, COSV55104088; called by muse, mutect2, varscan2
- MAGI2 | c.2964C>A p.H988Q | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62643489; called by muse, mutect2, varscan2
- MGAT4C | c.487C>A p.H163N | Missense Mutation (SNP) | VAF 41/272 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV59831451; called by muse, mutect2, varscan2
- MGAT4C | c.486C>A p.H162Q | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.093); catalogued as rs757539324, COSV59829660, COSV59831463; called by muse, mutect2, varscan2
- MRPS14 | c.101T>C p.M34T | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs1220495628, COSV62880124; called by muse, mutect2, varscan2
- NCOA2 | c.1070G>T p.R357L | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV71763729, COSV71764052; called by muse, mutect2, varscan2
- NF1 | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62198249; called by muse, mutect2, varscan2
- NIPAL2 | c.541C>A p.Q181K | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.437); catalogued as COSV57839001; called by muse, mutect2, varscan2
- NTRK3 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs1385327853, COSV58116009; called by muse, mutect2, varscan2
- OR4C16 | c.568A>C p.T190P | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58941341; called by muse, mutect2, varscan2
- OR4P4 | c.571C>A p.H191N | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV58921324, COSV58923417; called by muse, mutect2, varscan2
- OR51T1 | c.812C>A p.P271Q | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59024556; called by muse, mutect2, varscan2
- OR5AS1 | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 58/378 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV57981301; called by muse, mutect2, varscan2
- OR5V1 | c.863T>C p.I288T | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV65827056; called by muse, mutect2, varscan2
- OR6S1 | c.49G>C p.A17P | Missense Mutation (SNP) | VAF 57/348 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57837833; called by muse, mutect2, varscan2
- PCDH10 | c.1270G>T p.E424* | Nonsense Mutation (SNP) | VAF 90/339 reads (27%) | catalogued as COSV52094299; called by mutect2, varscan2
- PDE6B | c.1236A>C p.E412D | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.219); catalogued as COSV55325142; called by muse, mutect2, varscan2
- PDZRN3 | c.2462C>A p.T821N | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV55195084, COSV55210633; called by muse, mutect2, varscan2
- PEX5 | c.1775C>T p.P592L (on ENST00000420616; = p.P584L on NM_000319.5) | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV56953928; called by muse, mutect2, varscan2
- PIK3CG | c.502G>T p.V168L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV63247149, COSV63247160; called by mutect2, varscan2
- PITX2 | c.640C>A p.P214T (on ENST00000354925 / NM_001204397.1; = p.P221T on NM_000325.6) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV60740644; called by muse, mutect2, varscan2
- PKHD1L1 | c.2177C>A p.A726E | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV65740312; called by muse, mutect2, varscan2
- PLAA | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.904); catalogued as COSV68304706; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1143C>A p.H381Q (on ENST00000352766; = p.H302Q on NM_181334.5) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.007); catalogued as COSV61232439; called by muse, mutect2, varscan2
- PXDN | c.1790G>T p.R597L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.946); catalogued as COSV53230257, COSV53231780; called by muse, varscan2
- RASGRF2 | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV54126640; called by muse, mutect2, varscan2
- RIT2 | c.536G>A p.R179K | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV58662324; called by muse, mutect2, varscan2
- RPGRIP1 | c.2700A>T p.E900D | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV52847455; called by muse, mutect2, varscan2
- RSF1 | c.1783T>C p.F595L | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV57838181; called by muse, mutect2, varscan2
- S1PR4 | c.1103G>C p.S368T | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as COSV55739889; called by muse, mutect2, varscan2
- SCN2A | c.399G>T p.M133I | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV51836794; called by muse, mutect2, varscan2
- SLC17A6 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54133992, COSV54134887; called by muse, mutect2, varscan2
- SLC6A15 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 85/344 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1470317265, COSV57021625; called by muse, mutect2, varscan2
- SLC6A2 | c.1711A>T p.I571F | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV54915124; called by muse, mutect2, varscan2
- SMAD1 | c.1318C>G p.L440V | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV57470691; called by muse, mutect2, varscan2
- SPINK13 | c.216T>A p.C72* | Nonsense Mutation (SNP) | VAF 20/103 reads (19%) | catalogued as COSV68241321; called by muse, mutect2, varscan2
- SUCO | c.101C>G p.S34* | Nonsense Mutation (SNP) | VAF 17/95 reads (18%) | catalogued as COSV55263593, COSV55265161; called by muse, mutect2, varscan2
- TAPBP | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV70456913; called by muse, mutect2
- TENM3 | c.6344G>C p.R2115T | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as COSV69303355; called by muse, mutect2, varscan2
- TFPI2 | c.19dup p.L7Pfs*26 | Frame Shift Ins (INS) | VAF 22/82 reads (27%) | catalogued as rs745426990; called by mutect2, varscan2
- TMEM260 | c.1501G>T p.G501* | Nonsense Mutation (SNP) | VAF 32/135 reads (24%) | catalogued as COSV55097990; called by muse, mutect2, varscan2
- TNKS | c.1121A>G p.H374R | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV60054504; called by muse, mutect2, varscan2
- TNS1 | c.1685A>T p.E562V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV50695599; called by muse, mutect2, varscan2
- TRAPPC11 | c.3028G>T p.E1010* | Nonsense Mutation (SNP) | VAF 41/231 reads (18%) | catalogued as COSV58215575; called by muse, mutect2, varscan2
- TRPA1 | c.1688C>A p.A563D | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100083487, COSV51558473; called by muse, mutect2, varscan2
- TSHR | c.405C>G p.N135K | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53317280; called by muse, mutect2
- TTC27 | c.2095G>T p.G699C | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58650271; called by muse, mutect2, varscan2
- TTN | c.57044C>T p.T19015I (on ENST00000591111; = p.T11591I on NM_003319.4) | Missense Mutation (SNP) | VAF 70/342 reads (20%) | PolyPhen probably damaging (0.998); catalogued as rs1363633199, COSV59964574; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUT1 | c.2344C>A p.R782S | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53469375; called by muse, mutect2, varscan2
- UBR1 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 18/282 reads (6%) | catalogued as COSV51927474, COSV51928046; called by muse, mutect2
- UBR2 | c.4281G>T p.L1427F | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV65749566; called by muse, mutect2
- USH2A | c.2167+1G>C p.X723_splice | Splice Site (SNP) | VAF 13/32 reads (41%) | catalogued as COSV56349268; called by muse, mutect2, varscan2
- VCAN | c.591C>G p.D197E | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54101677; called by muse, mutect2, varscan2
- VGLL1 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs138345606, COSV65703134; called by muse, mutect2, varscan2
- VIRMA | c.2259T>G p.I753M | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV52583521; called by muse, mutect2
- WBP11 | c.387G>A p.K129= | Splice Region (SNP) | VAF 47/150 reads (31%) | catalogued as COSV53762385; called by muse, varscan2
- WDR70 | c.929C>A p.T310K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as COSV54270031; called by muse, varscan2
- WIF1 | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54130627; called by muse, mutect2, varscan2
- XIRP2 | c.3712A>G p.I1238V (on ENST00000628543; = p.I1413V on NM_152381.6) | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV54691019; called by muse, mutect2, varscan2
- ZBED9 | c.1856G>A p.C619Y | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV71729266; called by muse, mutect2, varscan2
- ZBED9 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV101509359, COSV71729267; called by muse, mutect2, varscan2
- ZC3H6 | c.668A>G p.K223R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV59666863; called by muse, mutect2, varscan2
- ZNF512 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); catalogued as COSV62674621; called by muse, mutect2, varscan2
- ZSWIM4 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 57/275 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV54320480; called by muse, mutect2, varscan2
- ATP5PF | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL28A1 | c.2834_2850del p.F945Sfs*5 | Frame Shift Del (DEL) | VAF 26/140 reads (19%) | called by mutect2, pindel
- CYFIP1 | c.2395G>A p.D799N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2
- OR8G2P | c.381C>A p.C127* | Nonsense Mutation (SNP) | VAF 66/333 reads (20%) | called by muse, mutect2, varscan2
- PLXNB2 | c.4288_4290delinsG p.H1430Afs*27 | Frame Shift Del (DEL) | VAF 45/295 reads (15%) | called by pindel, varscan2*
- TP53 | c.755_757del p.L252_T253delinsP | In Frame Del (DEL) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- ABCB11 | c.3837C>T p.T1279= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as rs1187121357, COSV55587976; called by muse, mutect2, varscan2
- ABCC8 | c.3552G>A p.A1184= | Silent (SNP) | VAF 14/196 reads (7%) | catalogued as rs144207158; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- ADAM23 | c.1746A>T p.P582= | Silent (SNP) | VAF 32/150 reads (21%) | catalogued as COSV52211332; called by muse, mutect2, varscan2
- ADAMTS17 | c.2835C>T p.T945= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as rs768358145, COSV51476492; called by muse, mutect2, varscan2
- AKAP13 | c.6912G>A p.G2304= (on ENST00000394518 / NM_007200.5; = p.G2308= on NM_006738.6) | Silent (SNP) | VAF 35/143 reads (24%) | catalogued as COSV63452670; called by muse, mutect2, varscan2
- ALDOA | c.579G>A p.K193= (on ENST00000642816 / NM_001243177.4; = p.K139= on NM_184041.5) | Silent (SNP) | VAF 30/183 reads (16%) | catalogued as COSV57632352; called by muse, mutect2, varscan2
- AP4B1 | c.210G>T p.L70= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as COSV56724125; called by muse, mutect2, varscan2
- BANP | c.741G>A p.T247= (on ENST00000286122; = p.T216= on NM_017869.4) | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV53735569; called by muse, mutect2
- BCL2L14 | c.375G>T p.S125= | Silent (SNP) | VAF 33/284 reads (12%) | catalogued as rs748708542, COSV53785220, COSV53793545; called by muse, mutect2
- CACNA1G | c.2229G>A p.K743= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV61721552; called by muse, mutect2, varscan2
- CD5 | c.108G>A p.R36= | Silent (SNP) | VAF 44/194 reads (23%) | catalogued as rs141935047; called by muse, mutect2, varscan2
- CHRNA1 | c.708C>T p.S236= (on ENST00000261007 / NM_001039523.3; = p.S211= on NM_000079.4) | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as COSV53682344; called by muse, mutect2, varscan2
- CNMD | c.285G>A p.G95= | Silent (SNP) | VAF 26/201 reads (13%) | catalogued as COSV65032736; called by muse, mutect2, varscan2
- CRX | c.438G>A p.L146= | Silent (SNP) | VAF 48/187 reads (26%) | catalogued as COSV55757618; called by muse, mutect2, varscan2
- CSPG5 | c.1281C>A p.G427= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV53130461; called by muse, mutect2, varscan2
- CYP7A1 | c.1410A>T p.I470= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as rs1297890440, COSV56963036; called by muse, mutect2, varscan2
- DEPDC1 | c.804T>C p.Y268= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as rs771136769, COSV63957897; called by muse, mutect2, varscan2
- DGKB | c.2214G>T p.R738= | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as COSV51771709; called by muse, mutect2, varscan2
- DRD5 | c.1068C>T p.P356= | Silent (SNP) | VAF 31/156 reads (20%) | catalogued as rs747104610, COSV58577435; called by muse, mutect2, varscan2
- EIF4G2 | c.2256A>G p.K752= | Silent (SNP) | VAF 45/179 reads (25%) | catalogued as rs1260169242, COSV60596660; called by muse, mutect2, varscan2
- FAM13A | c.1863C>T p.Y621= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as rs370077117; called by muse, mutect2, varscan2
- FRZB | c.405C>T p.A135= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV54553553; called by muse, mutect2, varscan2
- HIRA | c.1383C>A p.I461= | Silent (SNP) | VAF 28/286 reads (10%) | catalogued as COSV54273622, COSV54281094; called by muse, mutect2
- HTR2C | c.879G>A p.E293= | Silent (SNP) | VAF 64/138 reads (46%) | catalogued as rs782711180, COSV52205574; called by muse, mutect2, varscan2
- HTR3A | c.1236G>T p.S412= | Silent (SNP) | VAF 42/194 reads (22%) | catalogued as COSV55468667, COSV55471444; called by muse, mutect2, varscan2
- LRRC37A3 | c.147G>T p.L49= | Silent (SNP) | VAF 17/258 reads (7%) | catalogued as rs753910380; called by muse, mutect2
- MUC17 | c.2046T>G p.T682= | Silent (SNP) | VAF 122/609 reads (20%) | catalogued as COSV60284157; called by muse, mutect2, varscan2
- MYO5B | c.2277G>A p.L759= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV53215112; called by muse, mutect2, varscan2
- NSD1 | c.2016A>T p.T672= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as COSV61773781; called by muse, varscan2
- NT5E | c.1419T>C p.D473= | Silent (SNP) | VAF 56/314 reads (18%) | catalogued as rs1015716854, COSV57627862; called by muse, mutect2, varscan2
- OR4S2 | c.222C>G p.V74= | Silent (SNP) | VAF 77/197 reads (39%) | catalogued as COSV56746350; called by muse, mutect2, varscan2
- PCDH10 | c.900T>C p.L300= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV52090626; called by muse, mutect2, varscan2
- PDE10A | c.2244G>T p.T748= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV63093969; called by muse, mutect2, varscan2
- PLA2G2C | c.159C>A p.I53= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV56124267; called by muse, mutect2, varscan2
- PRG4 | c.1914G>A p.E638= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV63355188; called by muse, mutect2, varscan2
- PRICKLE4 | c.786G>T p.L262= (on ENST00000359201; = p.L302= on NM_013397.6) | Silent (SNP) | VAF 39/175 reads (22%) | catalogued as COSV59254265; called by muse, mutect2, varscan2
- PXDN | c.1791G>T p.R597= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV53230234; called by muse, varscan2
- RPL6 | c.435C>T p.T145= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV52516833; called by mutect2, varscan2
- SMARCA5 | c.2736A>G p.Q912= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV51643233; called by muse, mutect2, varscan2
- SNU13 | c.213G>A p.L71= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as COSV53237901; called by muse, mutect2, varscan2
- SPPL2B | c.168G>T p.P56= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV66316866; called by muse, mutect2
- SV2B | c.526C>A p.R176= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as COSV57699160, COSV57701375; called by muse, mutect2, varscan2
- TAF6 | c.187C>A p.R63= | Silent (SNP) | VAF 40/177 reads (23%) | catalogued as COSV59841021, COSV59841083; called by muse, mutect2, varscan2
- TAS2R16 | c.369G>A p.L123= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV50796964; called by muse, mutect2, varscan2
- TRIM51 | c.846C>A p.L282= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV55265252; called by muse, mutect2, varscan2
- UNC13B | c.1887C>T p.V629= | Silent (SNP) | VAF 51/282 reads (18%) | called by muse, varscan2
- USP42 | c.972C>T p.T324= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs151011297, COSV60358938; called by muse, mutect2, varscan2
- WNT2 | c.552C>A p.A184= | Silent (SNP) | VAF 30/192 reads (16%) | catalogued as COSV55410314; called by muse, mutect2, varscan2
- ZNF93 | c.1083C>T p.F361= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as rs1052463695, COSV59374804; called by muse, mutect2, varscan2
- DLG2 | c.205-65666G>C | Intron (SNP) | VAF 48/252 reads (19%) | called by muse, mutect2, varscan2
- NPAP1 | c.*1G>A | 3'UTR (SNP) | VAF 15/100 reads (15%) | catalogued as COSV100275573; called by muse, mutect2
- OR52A4P | n.907G>A | RNA (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- PNKD | c.236+1117G>A | Intron (SNP) | VAF 73/413 reads (18%) | called by muse, mutect2, varscan2
